Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4699, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4699-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1:

TENTH RIB, REMOVAL –

CARTILAGE, BONE AND BONE MARROW; NO SIGNIFICANT PATHOLOGIC CHANGES.

PART 2:

RIGHT KIDNEY, ADRENAL GLAND AND SEGMENT OF COLON, RADICAL NEPHRECTOMY WITH PARTIAL COLECTOMY –

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN'S NUCLEAR GRADE 4 OF 4 WITH SARCOMATOID DE-DIFFERENTIATION, 15 cm IN GREATEST DIMENSION.
- B. THE RENAL CELL CARCINOMA INVADES THE PERINEPHRIC ADIPOSE TISSUE AND THE COLONIC WALL TO THE LEVEL OF MUSCULARIS PROPRIA.
- C. FOCI OF ANGIOLYMPHATIC INVASION ARE IDENTIFIED.
- D. VASCULAR RESECTION MARGINS (RENAL AND COLONIC) ARE NEGATIVE FOR NEOPLASIA.
- E. URETERAL RESECTION MARGIN IS NEGATIVE FOR NEOPLASIA.
- F. RENAL CELL CARCINOMA IS IDENTIFIED ON THE INKED PERITONEAL SURFACE.
- G. PROXIMAL AND DISTAL RESECTION MARGINS ON THE COLON ARE NEGATIVE FOR NEOPLASIA.
- H. NO EVIDENCE OF NEOPLASIA IS PRESENT ON THE POSTERIOR ASPECT OF GEROTA'S FASCIA.
- I. ADRENAL GLAND SHOWS NO EVIDENCE OF NEOPLASIA AND NO SIGNIFICANT PATHOLOGIC CHANGES.
- J. THE NON-NEOPLASTIC RENAL PARENCHYMA SHOWS NO SIGNIFICANT PATHOLOGIC FINDINGS.
- K. THE NON-NEOPLASTIC COLON SHOWS NO SIGNIFICANT PATHOLOGIC FINDINGS.
- L. PATHOLOGIC TNM STAGING: pT4 N0 M1.

PART 3:

RETROCAVAL LYMPH NODE, EXCISION –

- A. NO EVIDENCE OF NEOPLASIA IN 5 LYMPH NODES EXAMINED.
- B. NERVOUS GANGLION WITH NO SIGNIFICANT PATHOLOGIC CHANGES.

PART 4:

INTER-AORTIC-CAVAL LYMPH NODE, EXCISION –

REACTIVE LYMPH NODE WITH NO EVIDENCE OF NEOPLASIA.

PART 5:

DUODENAL MARGIN, BIOPSY –

SARCOMATOID RENAL CELL CARCINOMA.

PART 6:

OMENTUM NODULE, RESECTION –

SARCOMATOID RENAL CELL CARCINOMA.

PART 7:

SMALL BOWEL ADHESION –

SARCOMATOID RENAL CELL CARCINOMA.

PART 8:

NODULE ON THE DIAFRAGM, RESECTION –

SARCOMATOID RENAL CELL CARCINOMA.

PART 9:

CECUM, PARTIAL COLECTOMY –

CECUM, APPENDIX AND TERMINAL ILEUM WITH NO EVIDENCE OF NEOPLASIA.

PART 10:

OMENTUM, RESECTION –

- A. SARCOMATOID RENAL CELL CARCINOMA.
- B. FAT NECROSIS.

PART 11:

DUODENAL NODULE, RESECTION –

HYALINIZED FIBROUS TISSUE WITH NO EVIDENCE OF NEOPLASIA.

PART 12:

RIGHT PLEURA PLAQUE, RESECTION –

- A. HYALINIZED FIBROUS TISSUE WITH DYSTROPHIC CALCIFICATION.
- B. NO EVIDENCE OF NEOPLASIA.

PART 13:

FRAGMENT OF TUMOR FROM PART 2, SAMPLING IN THE GROSSING ROOM –

TISSUE SENT FOR CYTOGENETIC STUDIES. RESULTS TO FOLLOW IN AN ADDENDUM.

Source: NCI Genomic Data Commons file 3a210035-acc5-4192-ba92-0fa914eed007 (TCGA-B0-4699.8C37CD5C-B75F-4110-8EE6-23EAF7DE741A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).